Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4351, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4351-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

with gallstones and left renal mass.

Specimens Submitted:

- 1: GALLBLADDER; CHOLECYSTECTOMY
- 2: KIDNEY AND ADRENAL, LEFT, DISTAL PANCREAS, SPLEEN; RADICAL NEPHRECTOMY, DISTAL PANCREATECTOMY, SPLENECTOMY
- 3: LYMPH NODES, AORTIC; EXCISION
- 4: LYMPH NODES, PERIHILAR; EXCISION
- 5: LYMPH NODES, INNER AORTIC CAVAL; EXCISION
- 6: SOFT TISSUE, PARARENAL FAT; EXCISION

DIAGNOSIS:

1. GALLBLADDER; CHOLECYSTECTOMY:

Benign gall bladder with chronic cholecystitis and cholelithiasis
Diffuse polypoid adenomyomatous hyperplasia
One lymph node, negative for carcinoma (0/1)

2. KIDNEY AND ADRENAL, LEFT, DISTAL PANCREAS, SPLEEN; RADICAL NEPHRECTOMY, DISTAL PANCREATECTOMY, SPLENECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 16.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes, and focal interstitial chronic inflammation

Adrenal Gland:

Not involved

Lymph Nodes:

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Free of tumor
Number of nodes examined:1

Staging for renal cell carcinoma/oncocytoma:
pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Comment:

A separate 1.8 cm, hyalinized, calcified/ focally ossified nodule, away from the main tumor mass in the kidney is also identified
Sections from pancreas show focal, mild chronic pancreatitis with fibrosis, and focal peripancreatic fat necrosis with saponification.
Sections of spleen are unremarkable.
Neither pancreas, nor spleen show involvement by renal cell carcinoma.

3. LYMPH NODES, AORTIC; EXCISION

Lymph Nodes:
Not involved
Number of nodes examined:6

4. LYMPH NODES, PERIHILAR; EXCISION

Lymph Nodes:
Not involved
Number of nodes examined:4

5. LYMPH NODES, INNER AORTIC CAVAL; EXCISION

Lymph Nodes:
Not involved
Number of nodes examined:5

6. SOFT TISSUE, PARARENAL FAT; EXCISION

Fibrovascular and adipose tissue, negative for carcinoma.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1).The specimen is received fresh for frozen section consultation, labeled "gallbladder and gallstones" and consists of a previously opened gallbladder measuring 11.5 cm in length and 4.9 cm in maximal diameter and three large multifaceted greenish yellow to black gallstones measuring in aggregate 7.9 x 4.5 x 3.6 cm. The surface of the gallbladder is inked black. There are numerous pinkish yellow polypoid projections of the mucosa covering the majority of the mucosal surface. These projections approach the cystic duct margin to within 0.8 cm. On section they appear confined to mucosa. The cystic duct margin and representative sections of the mucosa are submitted for frozen section. Representatively submitted. Photographs are taken.

Summary of sections:

FSCA -- frozen section control (cystic duct margin)
FSCB -- frozen section control (gallbladder mucosa)
FSCC -- frozen section control (gallbladder mucosa)

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

R -- representative sections

2) The specimen is received fresh labeled "left radical nephrectomy, distal pancreatectomy and splenectomy" and consists of a kidney with attached ureter, renal vessels, perinephric fat, with attached spleen and distal pancreas weighing 2117 g in total. The kidney is enlarged and distorted and measures 21.0 x 18.0 x 8.5 cm. The attached ureter measures 2.5 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.0 cm in length and 1.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 5.8 x 2.3 x 0.4 cm. The kidney is inked black and bivalved to reveal a large tumor measuring 16.0 x 15.5 x 8.5 cm. The tumor replaces almost entire kidney leaving a rim of renal parenchyma measuring 1.4 to 2.0 cm in thickness. The cut surface of tumor shows a variegated appearance with tan-yellow, tan-white myxoid and hemorrhagic areas. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm with the calyces and the pelvis are distorted by the tumor. The tumor grossly does not infiltrate the pelvis. Single lymph node is identified in the perinephric fat measuring 0.4 cm in maximum dimension. A calcified encapsulated mass is attached to the outer surface of kidney away from tumor measuring 1.8 x 1.7 x 1.0 cm. The attached spleen measures 14.5 x 8.5 x 4.2 cm and weighs 205 g. The splenic capsule is unremarkable and the cut surface shows unremarkable dark maroon parenchyma. The distal end of pancreas measures 5.5 x 5.5 x 1.4 cm. The pancreatic resection margin is identified. Neither the pancreas, nor the spleen are grossly invaded by tumor. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

AD -- adrenal gland

PAM -- pancreatic resection margin

PA -- pancreas

SP -- spleen

LN -- lymph node

M -- calcified mass attached to kidney

3). The specimen is received in formalin, labeled "aortic nodes" and consists of multiple pink-tan firm lymph nodes ranging from 0.3 – 5.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

SSLN-- one lymph node in three cassettes

4). The specimen is received in formalin, labeled "Perihilar nodes" and consists of a fragment of adipose tissue without grossly identifiable lymph nodes measuring 2.5 x 1.8 x 1.0 cm. Entirely submitted.

Summary of sections:

U - undesignated

5). The specimen is received in formalin, labeled "inner aortic caval nodes" and consists of multiple pink-tan firm lymph nodes ranging from 0.5 to 2.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

6).The specimen is received in formalin, labeled "pararenal fat" and consists of a 11.5 x 2.5 x 1.5 cm fragment of yellow adipose tissue with a 10.5 x 0.8 cm grossly unremarkable fragment of vein. Representative sections submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: GALLBLADDER; CHOLECYSTECTOMY

Block	Sect. Site	PCs
1	FSCA	1
1	FSCB	1
1	FSCC	1
8	R	8

Part 2: KIDNEY AND ADRENAL, LEFT, DISTAL PANCREAS, SPLEEN; RADICAL NEPHRECTOMY, DISTAL PANCREATECTOMY, SPLENECTOMY

Block	Sect. Site	PCs
1	AD	2
1	K	1
1	LN	1
1	M	2
1	PA	1
1	PAM	2
1	RP	1
1	SP	2
7	T	7
1	THF	1
1	TK	1
1	TSF	1
1	UVM	3

Part 3: LYMPH NODES, AORTIC; EXCISION

Block	Sect. Site	PCs
2	In	2
3	ssIn	3

Part 4: LYMPH NODES, PERIHILAR; EXCISION

Block	Sect. Site	PCs
2	u	2

Part 5: LYMPH NODES, INNER AORTIC CAVAL; EXCISION

Block	Sect. Site	PCs
2	In	2

Part 6: SOFT TISSUE, PARARENAL FAT; EXCISION

Block	Sect. Site	PCs
2	u	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

consultation.

- 1A) FROZEN SECTION DIAGNOSIS: POORLY ORIENTED CYSTIC DUCT MARGIN; DEFER TO PERMANENT FOR
FINAL DIAGNOSIS. (BDC)
PERMANENT DIAGNOSIS: SAME
- 1B,C) FROZEN SECTION DIAGNOSIS: BENIGN GALLBLADDER EPITHELIUM.
PERMANENT DIAGNOSIS: SAME
-

Source: NCI Genomic Data Commons file 34f9f009-243e-47ef-9703-d345e1fdd1ba (TCGA-BP-4351.0E118C8D-FC10-4298-921C-8B419014F7D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).